Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4882, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4882-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT ADRENAL SPARING RADICAL NEPHRECTOMY:

RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN NUCLEAR GRADE 3 (7.0 CM IN DIAMETER).

TUMOR EXTENDS TO ADIPOSE TISSUE OF THE RENAL SINUS.

Margins of resection free of tumor.

(B) REGIONAL LYMPH NODE:

One lymph node, no tumor present (0/1).

(C) ADDITIONAL REGIONAL LYMPH NODE:

One lymph node, negative for tumor (0/1).

GROSS DESCRIPTION

(A) RIGHT ADRENAL SPARING RADICAL NEPHRECTOMY - A kidney with surrounding perinephric fat measuring overall 19.0 x 11.0 x 5.5 cm. Cut section reveals a yellow variegated, well-circumscribed mass in the lower pole of the kidney measuring 7.0 x 6.0 x 5.0 cm. The tumor appears to infiltrate focally into the renal sinus and pushes into the perinephric fat. The uninvolved renal parenchyma appears unremarkable. The renal vein and ureter margins are negative for gross tumor. One possible lymph node is identified adjacent to the renal hilum (0.5 x 0.4 x 0.3 cm). No adrenal gland is identified.

SECTION CODE: A1, renal vein margin, ureter margin and one possible lymph node; A2, tumor to perinephric fat; A3 and A4, tumor to renal sinus; A5-A6, tumor to renal parenchyma; A7-A8, tumor; A9, uninvolved renal parenchyma.

(B) REGIONAL LYMPH NODE - A single lymph node measures 4.0 x 2.0 x 0.8 cm. The specimen is serially sectioned and entirely submitted in B1-B3.

(C) ADDITIONAL REGIONAL LYMPH NODE - A single lymph node measures 2.0 x 1.0 x 0.6 cm. The specimen is serially sectioned and entirely submitted in C1 through C2.

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, M-73123

Source: NCI Genomic Data Commons file c793ccd4-28e3-4cd0-acf1-54535d1a4e55 (TCGA-CJ-4882.7DB81E82-66A5-403A-A60A-F6508CA1119F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).